MMRF case MMRF_2271 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0bd0961e-3381-4fbd-9cd6-f80640317a14

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 88 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 88.6 years (32,353 days); ISS stage: I; Days to last known disease status: 819 days (2.2 years); Days to last follow up: 518 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 154 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -21 (ECOG 2): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 175 mg/dL; Immunoglobulin G 2.71 g/L; Immunoglobulin A 7.64 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 346 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 7.5 g/dL; Glucose 5.56 mmol/L.
- Day 36 (ECOG 2): M Protein 1.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 271 mg/dL; Immunoglobulin G 2.54 g/L; Immunoglobulin A 15.5 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 406 ×10⁹/L; Creatinine 61 µmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 5.17 mmol/L.
- Day 147 (ECOG 3): Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 354 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6 g/dL; Glucose 3.85 mmol/L.
- Day 210 (ECOG 2): Hemoglobin 8.18 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L.
- Day 343 (ECOG 1): Hemoglobin 8.99 mmol/L; Leukocytes 7.8 ×10⁹/L; Platelets 33 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 7.32 mmol/L.
- Day 434 (ECOG 0): Lactate Dehydrogenase 2.3 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 280 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L.
- Day 518 (ECOG 0): M Protein 0.7 g/dL; Immunoglobulin G 6.45 g/L; Immunoglobulin A 6.93 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.37 mmol/L; Leukocytes 8.9 ×10⁹/L; Platelets 307 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L.

Other clinical attributes
- Day -21: Weight: 59 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Melanoma.

Biospecimens (2 samples)
- Sample MMRF_2271_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -21 days.
- Sample MMRF_2271_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -21 days.
